Somatic mutation profile of tumor specimen 0DJZER from CCDI case PBBXNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (535 days).
Specimen 0DJZER: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dec9997-d22a-43a9-9640-28bf866d6980.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJZES (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae3ac2aa-c2dc-4e9a-bc9d-72699f6fc53f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MOGAT3 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 232/598 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV99777127; called by muse, varscan2
- ZNF329 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRUNE2 | c.*60A>G | 3'UTR (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
